Gene-level copy-number profile of tumor specimen ALCH-B53R-TTP1-A from ALCHEMIST case ALCH-B53R, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.8 years (22,944 days).
Specimen ALCH-B53R-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1d7af4e8-6ade-4ecb-9d2c-6b6f613c8a68.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B53R-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/bf6788db-6c66-479d-a69d-7b92b562511a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 83; copy number 1: 9,643; copy number 2: 45,924; copy number 3: 2,574; copy number 4: 89; copy number 5: 55; copy number 6: 14; copy number 10: 3; copy number 11: 2; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:232,343,116–232,351,309, 2 genes (within-gene range 0–2): NRBF2P6, ECEL1P3.
- chr3:47,495,640–47,513,712, 2 genes: ELP6, BOLA2P2.
- chr6:158,764,661–158,764,753, 1 gene (within-gene range 0–2): MIR3918.
- chr7:75,156,639–75,327,765, 12 genes: NCF1C, GTF2IP1, PHBP6, AC211486.5, AC211486.2, AC211486.4, SPDYE13, PMS2P10, Y_RNA, SPDYE14, AC211486.3, Y_RNA.
- chr13:19,818,121–19,818,619, 1 gene: ST6GALNAC4P1.
- chr15:25,169,337–25,257,027, 46 genes (within-gene range 0–1): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr15:43,276,271–43,302,255, 1 gene (within-gene range 0–1): TGM7.
- chr18:37,273,706–37,276,572, 1 gene (within-gene range 0–1): AC090386.1.
- chr18:78,505,165–78,506,410, 1 gene: AC012572.1.
- chr19:41,829,692–41,844,697, 3 genes: HNRNPA1P52, AC243967.3, LYPD4.
- chr20:3,686,970–3,707,128, 1 gene: SIGLEC1.
- chr21:14,000,927–14,144,468, 7 genes (within-gene range 0–1): NF1P3, PPP6R2P1, FRG2MP, AP001347.1, ANKRD20A18P, RNA5SP488, AP001347.2.
- chr22:29,058,672–29,061,844, 1 gene (within-gene range 0–2): C22orf31.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 75 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:55,235,965–56,381,312, 49 genes, copy number 5 (within-gene range 4–5): ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1, CCNJP1, AC073136.1, AC073136.2, AC093392.1, RNU6-1335P, SEPTIN14P24, CICP8, AC093392.2.
- chr7:74,796,144–74,851,551, 1 gene, copy number 13: GTF2IRD2.
- chr7:75,092,573–75,149,817, 1 gene, copy number 5: GTF2IRD2B.
- chr7:75,391,955–75,416,787, 3 genes, copy number 5–10 (within-gene range 2–10): AC211486.1, TRIM73, NSUN5P1.
- chr14:105,486,317–105,499,575, 3 genes, copy number 5–6: CRIP1, AL928654.3, TEDC1.
- chr17:19,092,974–19,188,714, 12 genes, copy number 6: AC007952.2, AC007952.4, SNORD3D, SNORD3D, GRAPL, AC007952.6, AC007952.9, AC007952.1, AC007952.5, AC007952.8, KYNUP1, SNORD3A.
- chr18:12,067,173–12,076,654, 2 genes, copy number 5: AP002414.4, AP002414.2.
- chr21:43,414,483–43,479,534, 4 genes, copy number 5–11: SIK1, LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 7,463. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
